Somatic mutation profile of tumor specimen MP2PRT-PATIEF-TMP1-A (aliquot MP2PRT-PATIEF-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATIEF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (2,014 days).
Specimen MP2PRT-PATIEF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35db701c-557b-408b-94fc-54d9dcda745d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATIEF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATIEF-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fe59dfb-2615-4909-9783-9b814bee3dff

The open-access MAF lists 36 somatic variants for this specimen: 31 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 4, Nonsense Mutation 3, Frame Shift Ins 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 102/206 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs376607329; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 136/273 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs541040666, COSV54029228; called by muse, mutect2, varscan2
- CYP11A1 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 86/202 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs773145475, COSV51430875, COSV99165888; called by muse, mutect2, varscan2
- DRD2 | c.1138G>A p.G380S | Missense Mutation (SNP) | VAF 12/279 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1266326437; called by muse, mutect2
- FLT3 | c.1798G>T p.D600Y | Missense Mutation (SNP) | VAF 84/182 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54071039; called by muse, mutect2, varscan2
- GRIA4 | c.2371G>A p.D791N | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1164181744, COSV56882979; called by muse, mutect2, varscan2
- HIVEP2 | c.2683G>A p.E895K | Missense Mutation (SNP) | VAF 122/418 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50021131; called by muse, mutect2, varscan2
- KIAA2026 | c.3140C>T p.P1047L | Missense Mutation (SNP) | VAF 113/274 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as rs200878405, COSV67357469; called by muse, mutect2, varscan2
- KMT2C | c.6034C>T p.P2012S | Missense Mutation (SNP) | VAF 111/266 reads (42%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); catalogued as rs768932767, COSV51364489; called by muse, mutect2, varscan2
- LRP1B | c.4022C>A p.T1341K | Missense Mutation (SNP) | VAF 132/298 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV101251406, COSV67257549; called by muse, mutect2, varscan2
- MAGEB6 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs201048484, COSV66872093, COSV66873453; called by muse, mutect2, varscan2
- MAPK4 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 146/325 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs926401405; called by muse, mutect2, varscan2
- MYO1D | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 105/248 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375202047; called by muse, mutect2, varscan2
- OBSCN | c.21523C>T p.R7175C | Missense Mutation (SNP) | VAF 180/416 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs993631362; called by muse, mutect2, varscan2
- PAPPA2 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 107/231 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as rs770493671, COSV100866600, COSV62776460; called by muse, mutect2, varscan2
- PCDHA4 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 114/298 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.282); catalogued as rs781997820, COSV63542572, COSV63544995; called by muse, mutect2, varscan2
- RIMS1 | c.2072G>A p.R691K | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53461662; called by muse, mutect2, varscan2
- RTP5 | c.527G>A p.W176* | Nonsense Mutation (SNP) | VAF 252/554 reads (45%) | catalogued as rs778687546, COSV100574722; called by muse, mutect2, varscan2
- AHNAK | c.4447C>T p.P1483S | Missense Mutation (SNP) | VAF 133/441 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ASXL2 | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 144/290 reads (50%) | called by muse, mutect2, varscan2
- DST | c.20685G>A p.W6895* (on ENST00000361203 / NM_001374722.1; = p.W4592* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 112/367 reads (31%) | called by muse, mutect2, varscan2
- GCKR | c.1258C>A p.Q420K | Missense Mutation (SNP) | VAF 100/204 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- GPATCH8 | c.190C>A p.Q64K | Missense Mutation (SNP) | VAF 96/206 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HYOU1 | c.1005T>A p.D335E | Missense Mutation (SNP) | VAF 92/317 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- IRF8 | c.239_240insCC p.L82Gfs*6 | Frame Shift Ins (INS) | VAF 108/294 reads (37%) | called by mutect2, varscan2
- IRF8 | c.240delinsCCC p.R81Pfs*7 | Frame Shift Ins (INS) | VAF 137/369 reads (37%) | called by mutect2*, pindel, varscan2*
- NUMA1 | c.1657G>A p.V553M | Missense Mutation (SNP) | VAF 165/490 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- PTCHD1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 188/370 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- SCN2A | c.4814C>A p.S1605Y | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SSU72P4 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 72/736 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.089); called by muse, mutect2
- UBR5 | c.1215+1G>A p.X405_splice | Splice Site (SNP) | VAF 60/140 reads (43%) | called by muse, mutect2, varscan2
- ALDH1A2 | c.63G>T p.A21= | Silent (SNP) | VAF 133/337 reads (39%) | catalogued as rs748689904, COSV51079370; called by muse, mutect2, varscan2
- HTR1A | c.855C>T p.D285= | Silent (SNP) | VAF 214/478 reads (45%) | catalogued as rs149284354; called by muse, mutect2, varscan2
- SLITRK5 | c.312C>T p.Y104= | Silent (SNP) | VAF 112/266 reads (42%) | catalogued as rs75498472; called by muse, mutect2, varscan2
- SPON1 | c.930G>A p.T310= | Silent (SNP) | VAF 118/342 reads (35%) | catalogued as rs371712958; called by muse, mutect2, varscan2
- CLEC20A | c.928+1720C>T | Intron (SNP) | VAF 153/390 reads (39%) | called by muse, mutect2, varscan2
